Somatic mutation profile of tumor specimen TCGA-13-1412-01A (aliquot TCGA-13-1412-01A-01W-0492-08) from TCGA case TCGA-13-1412, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 41.4 years (15,119 days).
Specimen TCGA-13-1412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 031aff09-964e-4dba-a34d-927c044dfdf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1412-10A (Blood Derived Normal), aliquot TCGA-13-1412-10A-01W-0493-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c26af36-4af7-48f3-ad77-9cc4d84288c3

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 17, Splice Site 3, 3'UTR 2, Nonsense Mutation 2, In Frame Del 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 157/222 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BUD23 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV99736893; called by muse, mutect2, varscan2
- CCAR1 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56268854; called by muse, mutect2, varscan2
- CHD4 | c.2950C>T p.L984F (on ENST00000357008 / NM_001363606.2; = p.L997F on NM_001273.5) | Missense Mutation (SNP) | VAF 141/452 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779545095, COSV58898367; called by muse, mutect2, varscan2
- CLIC2 | c.293+1G>A p.X98_splice | Splice Site (SNP) | VAF 23/168 reads (14%) | catalogued as COSV58936152; called by muse, mutect2, varscan2
- CSAG1 | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63400109, COSV63400725; called by muse, mutect2, varscan2
- DDX25 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54989445; called by muse, mutect2, varscan2
- EIF2B5 | c.1571G>A p.G524E (on ENST00000647909; = p.G516E on NM_003907.3) | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV56604224; called by muse, mutect2, varscan2
- FAM241B | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100958424, COSV64768184; called by muse, mutect2
- FLG | c.9253G>C p.G3085R | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.171); catalogued as rs761303232, COSV64240018; called by muse, mutect2, varscan2
- IGSF1 | c.3730C>G p.L1244V | Missense Mutation (SNP) | VAF 220/568 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63836889; called by muse, mutect2, varscan2
- KCNT2 | c.819+2T>A p.X273_splice | Splice Site (SNP) | VAF 58/170 reads (34%) | catalogued as COSV54073356; called by muse, mutect2, varscan2
- KIAA1755 | c.3500G>C p.S1167T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54075361, COSV54080236; called by muse, mutect2, varscan2
- KRTAP5-3 | c.179G>C p.C60S | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.733); catalogued as COSV101294525; called by muse, mutect2
- MPP7 | c.888G>C p.R296S | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV61731306; called by muse, mutect2, varscan2
- NODAL | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755603; called by mutect2, varscan2
- NUP214 | c.3310C>G p.Q1104E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63908675; called by muse, mutect2
- OR5H6 | c.539T>C p.F180S (on ENST00000642105; = p.F164S on NM_001005479.2) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV67351279; called by muse, mutect2, varscan2
- PDE6A | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV54926200; called by muse, mutect2, varscan2
- PKD2L1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 186/475 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58395484; called by muse, mutect2, varscan2
- PLEKHB2 | c.581A>T p.Y194F (on ENST00000409279; = p.Y193F on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV52175352; called by muse, mutect2, varscan2
- PROM2 | c.498-1G>A p.X166_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100469365; called by muse, mutect2, varscan2
- RELCH | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as rs367903884; called by muse, mutect2, varscan2
- SLC8A3 | c.2731C>A p.L911I (on ENST00000381269 / NM_183002.3; = p.L909I on NM_033262.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.994); catalogued as COSV99385829; called by mutect2, varscan2
- SNRNP200 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60488900; called by muse, mutect2, varscan2
- SYT12 | c.798G>T p.Q266H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV67353698; called by muse, mutect2, varscan2
- THOC2 | c.2883C>A p.D961E | Missense Mutation (SNP) | VAF 128/445 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV55543855; called by muse, mutect2, varscan2
- TKT | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1553677596, COSV99965144; called by muse, mutect2, varscan2
- TTN | c.75093G>C p.K25031N (on ENST00000591111; = p.K17607N on NM_003319.4) | Missense Mutation (SNP) | VAF 134/459 reads (29%) | PolyPhen probably damaging (0.997); catalogued as rs762254728, COSV59981517; called by muse, mutect2, varscan2
- UBB | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV56219267; called by muse, mutect2, varscan2
- NUMA1 | c.2174_2188del p.A725_L729del | In Frame Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- RGS22 | c.403del p.S135Vfs*9 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | called by mutect2, pindel, varscan2
- TOP2A | c.610_612del p.M204del | In Frame Del (DEL) | VAF 292/1294 reads (23%) | called by pindel, varscan2
- ZNF658 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 105/592 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2
- ADCK2 | c.396C>T p.H132= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99301847; called by muse, mutect2
- CACNA1E | c.3621C>T p.D1207= | Silent (SNP) | VAF 62/562 reads (11%) | catalogued as COSV62389305; called by muse, mutect2, varscan2
- CCNI2 | c.477G>C p.R159= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs765981033, COSV101107879; called by muse, mutect2, varscan2
- EML4 | c.12C>T p.F4= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1321827535, COSV59296728; called by muse, mutect2
- IGF2R | c.3033C>G p.L1011= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV100808107; called by muse, mutect2
- IGSF21 | c.1167C>T p.S389= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs368532350, COSV52135429; called by mutect2, varscan2
- MBTPS1 | c.1368C>G p.V456= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV58570195; called by muse, mutect2, varscan2
- MRRF | c.48C>T p.R16= | Silent (SNP) | VAF 168/587 reads (29%) | catalogued as COSV52913882; called by muse, mutect2, varscan2
- MUC17 | c.12300A>C p.T4100= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV60285340; called by muse, mutect2, varscan2
- NEK6 | c.696C>T p.S232= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1014777973, COSV57221856; called by muse, mutect2
- SPG7 | c.1188C>T p.C396= (on ENST00000268704; = p.C403= on NM_003119.4) | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- SV2A | c.486C>T p.G162= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as COSV64964530; called by muse, mutect2, varscan2
- TLR8 | c.1722A>T p.T574= (on ENST00000218032 / NM_138636.5; = p.T592= on NM_016610.4) | Silent (SNP) | VAF 79/117 reads (68%) | catalogued as COSV54317263; called by muse, mutect2, varscan2
- TOP2A | c.2304T>C p.I768= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV101396374; called by muse, mutect2, varscan2
- XDH | c.3618C>T p.L1206= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV101052454; called by muse, mutect2
- ZBP1 | c.213T>G p.T71= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV59061297, COSV59063172; called by muse, mutect2, varscan2
- ZC3H7B | c.904C>T p.L302= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100687733; called by muse, mutect2, varscan2
- CENPA | c.*2C>A | 3'UTR (SNP) | VAF 19/149 reads (13%) | catalogued as COSV99273265; called by muse, mutect2, varscan2
- LGR6 | c.213-11233G>T | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as rs1379987655; called by muse, mutect2
- SDC1 | c.*1C>T | 3'UTR (SNP) | VAF 18/70 reads (26%) | catalogued as rs376758793; called by muse, mutect2, varscan2
